National Lung Screening Trial (NLST) participant 130330 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 66 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 49): Negative screen, no significant abnormalities.
- T1 (day 395): Negative screen, significant abnormalities not suspicious for lung cancer.
- T2 (day 735): Negative screen, minor abnormalities not suspicious for lung cancer.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a negative screen; study year of the first confirmed lung cancer: T2; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,024, study year T2. Site: lower lobe of lung (ICD-O-3 C34.3), determined from cytology. Primary tumour location: left lower lobe. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: unspecified in pathology report. Tumour size on pathology: 50 mm. AJCC 6th edition staging: stage IV (best stage, from clinical TNM); clinical T2 N0 M1 (stage IV). AJCC 7th edition staging: stage IV; clinical T2a N0 M1b. Summary stage: distant.

Follow-up
Last known free of lung cancer: day 708.
